Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A44R, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A44R-06A (Metastatic).

Procurement Date: Laterality: Lymph node architectures are replaced by tumor cells. Tumor is composed of spindle or oval tumor cells with quite scant cytoplasm. Tumor cells have a quite low nucleo-cytoplasmic ratio. Nucleus varies in shape and size with large esinophilic nucleoli. Mitotic figures are common. Cytoplasm sometime contains finely divided melanin pigment granulaes

Path Report: Specimen type: Surgical resection

Tumor type: Metastatic neoplasm, malignant melanoma

Tumor site: Inguinal lymph node

Tumor size: (Lymph node) 2 x 1.5 x 1 cm

Lymph nodes: 1/1 positive (right inguinal)

ICD-O3

melanoma, NOS

8720/3

Site: lymph node, inguinal

8131.2
120

C77.4

8/14/12

Source: NCI Genomic Data Commons file f7e80e62-3dbe-4a09-bd90-d67d2b889ef6 (TCGA-EB-A44R.A1170F13-22F2-4A5B-9316-D35C17863E76.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).